Somatic mutation profile of tumor specimen TCGA-EK-A2R9-01A (aliquot TCGA-EK-A2R9-01A-11D-A18J-09) from TCGA case TCGA-EK-A2R9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 58.2 years (21,242 days).
Specimen TCGA-EK-A2R9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d82a552c-eaf7-4a70-b568-ee88d8f50587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2R9-10A (Blood Derived Normal), aliquot TCGA-EK-A2R9-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8aa4b81-987d-44e7-bbdd-dab2e53a16be

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Nonsense Mutation 6, Frame Shift Del 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC005324.2 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.876); catalogued as COSV60886871; called by muse, mutect2, varscan2
- ACTRT3 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100377315, COSV100377489; called by muse, mutect2
- ADCY6 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.652); catalogued as rs1386744112, COSV57168082; called by muse, mutect2, varscan2
- CCDC59 | c.401T>A p.L134* | Nonsense Mutation (SNP) | VAF 30/99 reads (30%) | catalogued as COSV50259189; called by muse, mutect2, varscan2
- CEP250 | c.6898T>A p.L2300M | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61170357; called by muse, mutect2, varscan2
- CEP72 | c.1572G>C p.L524F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53792945; called by muse, mutect2, varscan2
- CNTN1 | c.2687T>C p.I896T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs771657279, COSV61639916; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRTC3 | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV51596823; called by muse, mutect2, varscan2
- DPEP2 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.398); catalogued as rs976551789, COSV52054693; called by muse, mutect2, varscan2
- EGR1 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99525222; called by muse, mutect2
- FADD | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as COSV57229323, COSV57229544; called by muse, mutect2, varscan2
- FGFR2 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.059); catalogued as rs371596204; called by muse, mutect2, varscan2
- FTCD | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs140217223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDI1 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50131359, COSV50133037; called by muse, mutect2, varscan2
- GFRA3 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV51228745; called by muse, mutect2
- GOLGA3 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs572488166, COSV52631927; called by muse, mutect2, varscan2
- GPR20 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100897252; called by muse, mutect2, varscan2
- KLHL18 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs778008116, COSV51745861; called by muse, mutect2, varscan2
- LCE2C | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV64228437; called by muse, mutect2, varscan2
- LIN9 | c.904C>T p.R302C (on ENST00000366808 / NM_001270410.2; = p.R247C on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755213060, COSV60244939; called by muse, mutect2, varscan2
- MAGEB1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs145867809, COSV66775779; called by muse, mutect2, varscan2
- OR5M3 | c.800A>G p.E267G | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV56566899; called by muse, mutect2, varscan2
- OR6N2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.65); catalogued as rs774009483, COSV100210198, COSV59411070; called by muse, mutect2, varscan2
- PRAMEF4 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs267597988, COSV99339399; called by muse, mutect2, varscan2
- RANBP10 | c.1072T>A p.S358T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as COSV58157872; called by muse, mutect2, varscan2
- RYR2 | c.13900G>A p.V4634I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs756310498, COSV63666877; called by muse, mutect2
- SFRP4 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs555863176, COSV52259818; called by muse, mutect2, varscan2
- SLC8A1 | c.1820C>A p.S607* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV60481505; called by muse, mutect2, varscan2
- SLC9C1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as rs201401597, COSV59888400; called by muse, mutect2, varscan2
- SULT1E1 | c.488A>C p.Q163P | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as COSV56947226; called by muse, mutect2, varscan2
- SYNE1 | c.7597G>A p.E2533K (on ENST00000367255 / NM_182961.4; = p.E2540K on NM_033071.3) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as COSV54937930, COSV99559674; called by muse, mutect2, varscan2
- ZNF775 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.687); catalogued as COSV61613652; called by muse, mutect2, varscan2
- ZSWIM5 | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as rs771246734, COSV55800326; called by muse, mutect2, varscan2
- NPL | c.677dup p.T227Dfs*9 | Frame Shift Ins (INS) | VAF 23/85 reads (27%) | called by mutect2, pindel, varscan2
- PCDHGB6 | c.1034del p.P345Qfs*3 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | called by mutect2, pindel, varscan2
- TOM1 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- TRMT61B | c.542del p.N181Ifs*21 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- YY1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- ATP10D | c.3675C>T p.I1225= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV56707723, COSV56708851; called by muse, mutect2, varscan2
- ATP2B3 | c.1662G>A p.L554= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV54848211; called by muse, mutect2, varscan2
- CHRM3 | c.879C>T p.Y293= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs202068533, COSV99697286; called by muse, mutect2, varscan2
- CNTNAP2 | c.840C>A p.V280= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV62185185; called by muse, mutect2, varscan2
- DCAF15 | c.1428C>T p.I476= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs892949349, COSV99585712; called by muse, mutect2, varscan2
- EHD1 | c.1281C>T p.G427= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs763217436, COSV57734789; called by muse, mutect2, varscan2
- H2AP | c.291C>T p.S97= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs374389406, COSV61910780; called by muse, mutect2, varscan2
- KIAA1522 | c.1251C>T p.L417= (on ENST00000373480 / NM_001198972.2; = p.L476= on NM_020888.3) | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV53864735, COSV53865123; called by muse, mutect2, varscan2
- P3H2 | c.1077G>A p.P359= | Silent (SNP) | VAF 46/55 reads (84%) | catalogued as rs761021603, COSV60018421; called by muse, mutect2, varscan2
- PANX2 | c.828C>T p.R276= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV50296193; called by muse, mutect2, varscan2
- PIP4K2C | c.72C>T p.F24= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as COSV61605594, COSV61606167; called by muse, mutect2, varscan2
- SPEN | c.3120G>A p.V1040= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs755049645, COSV65362365; called by muse, mutect2, varscan2
- THEM6 | c.626G>A p.*209= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs144075334; called by muse, mutect2, varscan2
- CUEDC2 | chr10:102436582 C>T | 5'Flank (SNP) | VAF 14/30 reads (47%) | catalogued as rs767159998; called by muse, varscan2
